TCGA case TCGA-SB-A6J6 — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Baylor College of Medicine. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8b5bb660-c3c6-4ad6-9b32-e12d458b8ad7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 22 years; Year of birth: 1990; Vital status: Alive.

Diagnoses (1)
1. Seminoma, NOS: ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 22.5 years (8,233 days); Year of diagnosis: 2013; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 413 days (1.1 years); Ajcc serum tumor markers: S0.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (4 entries)
- Days to follow up: 105 days; Disease response: Tumor Free.
- Days to follow up: 384 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 413 days (1.1 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -13: Lactate Dehydrogenase 121; Alpha Fetoprotein 0.8.
- Day 98: Lactate Dehydrogenase 101; Alpha Fetoprotein 0.8.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not attempt to reproduce; Undescended testis history: No.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-SB-A6J6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 70 mg.
  Slide TCGA-SB-A6J6-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
- Sample TCGA-SB-A6J6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-SB-A6J6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; History hypospadias: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Testes; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology: Histologic diagnosis: Seminoma, NOS.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 121; Pre orchi afp: 0.8.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 101; Post orchi afp: 0.8.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- Follow-up form 1: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 413 days; disease-specific survival: no event (censored), 413 days; disease-free interval: no event (censored), 413 days; progression-free interval: no event (censored), 413 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-SB-A6J6-01A-11D-A434-01): tumor purity 0.28, ploidy 4.97, whole-genome doublings 2.
